Somatic mutation profile of tumor specimen TARGET-10-PASTLP-09A (aliquot TARGET-10-PASTLP-09A-01D) from TARGET case TARGET-10-PASTLP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,420 days).
Specimen TARGET-10-PASTLP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac867d69-60b0-4809-8dfe-e97cd39f5a47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASTLP-10A (Blood Derived Normal), aliquot TARGET-10-PASTLP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7307a0dd-2943-49be-9c9d-5c24b2462c24

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 3, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.7194G>C p.K2398N | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV71297005; called by muse, mutect2, varscan2
- ACTC1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.491); catalogued as rs397517072, COSV51759700; ClinVar: uncertain significance; called by muse, varscan2
- CCDC185 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs200981335, COSV64822212; called by muse, mutect2, varscan2
- CYP2C9 | c.1008C>A p.S336R | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs1450950019; called by muse, mutect2
- FAM151A | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs1470361727; called by muse, mutect2
- HIF1AN | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV54501281, COSV54502352; called by muse, mutect2, varscan2
- KCNH1 | c.1558C>T p.R520W (on ENST00000271751 / NM_172362.3; = p.R493W on NM_002238.4) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55076714; called by muse, mutect2, varscan2
- KCNS3 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs142972265, COSV100411116; called by muse, varscan2
- KMT2C | c.3341G>T p.C1114F | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51521419; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- NTF4 | c.249C>G p.S83R | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.9); PolyPhen benign (0.385); catalogued as COSV56825621; called by muse, mutect2, varscan2
- PHF6 | c.730-2A>G p.X244_splice (on ENST00000332070 / NM_032458.3; = p.X245_splice on NM_032335.3) | Splice Site (SNP) | VAF 29/31 reads (94%) | catalogued as COSV59698893; called by muse, mutect2, varscan2
- PHYKPL | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs774564514, COSV57424072, COSV57427668; called by muse, mutect2, varscan2
- RNPC3 | c.829C>A p.R277S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs989973373, COSV71076818; called by mutect2, varscan2
- SLC15A5 | c.605T>G p.L202R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61366225; called by muse, mutect2
- TBXT | c.851G>T p.S284I | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV51619852; called by muse, mutect2, varscan2
- WWC2 | c.2224G>A p.V742I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs201654424; called by muse, mutect2
- ZSCAN2 | c.1614C>A p.S538R | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV57572187; called by muse, mutect2
- CEP57L1 | c.53_54insTTGT p.E18Dfs*13 | Frame Shift Ins (INS) | VAF 22/42 reads (52%) | called by mutect2, varscan2
- LPCAT1 | c.309G>T p.M103I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.025); called by muse, mutect2
- MAP1B | c.2881C>A p.H961N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- SETDB2 | c.1035C>A p.C345* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- ASCC3 | c.5664C>T p.H1888= | Silent (SNP) | VAF 119/282 reads (42%) | called by muse, varscan2
- FBLN1 | c.2016C>T p.A672= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs775534608; called by muse, mutect2, varscan2
- PACSIN2 | c.1011G>T p.L337= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- PPP2R3A | c.1996-3633C>A | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
